Gene-level copy-number profile of tumor specimen C3L-03407-01 (profiled together with C3L-03407-02, C3L-03407-03, C3L-03407-04, C3L-03407-05) from CPTAC case C3L-03407, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 57.3 years (20,944 days).
Specimen C3L-03407-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4467afca-0271-4648-acd8-fd065bdda09a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-03407-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,247 have no estimate.
https://portal.gdc.cancer.gov/files/95a675a4-ea57-4d20-bb5e-93287193a093

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,443; copy number 2: 48,075; copy number 3: 6,858.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 3,443. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
